Surgical pathology report (de-identified scan), TCGA case TCGA-MM-A563, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MM-A563-01A (Primary Tumor).

[page 1 of 2]
Collection Date

Collection Time

Resulting Agency

SURGICAL PATHOLOGY

PATHOLOGIC DIAGNOSIS

KIDNEY, LEFT, RADICAL NEPHRECTOMY:

- CLEAR CELL (CONVENTIONAL) RENAL CARCINOMA
- 7.2 CM IN THE GREATEST DIMENSION
- FUHRMAN GRADE: G2
- TUMOR SITE: MID KIDNEY
- UNIFOCAAL TUMOR
- NO SARCOMATOID FEATURES IDENTIFIED
- NO TUMOR NECROSIS SEEN
- NO LYMPHOVASCULAR OR PERINERUAL INVASION IDENTIFIED
- TUMOR EXTENDS INTO RENAL CAPSULE, BUT NOT INTO PERINEPHRIC FAT
- MARGINS: FREE

Tumor Staging (Pathology)

Anatomic site of cancer: Left kidney

Histologic type: Clear cell renal carcinoma

Fuhrman grade: G2 Tumor size (cm): 7.2 cm

Primary tumor (T): T3

Lymph node (N): NX

Distant metastasis (M): MX

Stage grouping: Stage

Site of distant metastasis: Not known

Surgical margins: Free

102-0-3

carcinoma, clear cell (renal) 8310/3

Site: Kidney, nos c64.9

bu
11/25/12

Comment: The findings were communicated via email with Urology Department at

Staff Pathologist

Pertinent Clinical Information
year-old with renal mass.

Procedure: Left laparoscopic radical nephrectomy.

Gross Description

[page 2 of 2]
Specimen Material: Left kidney with mass.

The case is received in one part labeled with the patient's name, medical record number and given accession number , and it is accompanied by a requisition form labeled with the same name and accession number.

Received fresh labeled "LEFT KIDNEY WITH MASS" is a 480 gram, 17.5 x 10 x 6 cm left nephrectomy specimen containing a 11 x 5 x 3 cm kidney with a 5 cm in length x 0.2 cm in diameter ureter, with a 1.3 cm in length and 0.2 cm in diameter artery, and with a 0.3 cm in length and 0.8 cm in diameter vein.

There is abundant attached adipose tissue. No adrenal gland is identified. The margin is inked black. The cut surface displays a 7.2 x 6 x 4.5 cm lobulated, golden-yellow to red and variegated, incapsulated mass encircling pelvis and located in the middle segment of the kidney and is located 0.3 cm from the inked margin, involved the attached fat and is 7 cm from ureter 1.7 cm from the vein and abuts the artery.

The urothelium is gray-white and smooth. The remaining kidney parenchyma is homogenous and the cortical medullary junction is ill-defined. The cortex is 0.6 cm thick. No lymph node is identified.

Representative sections are submitted as follows:

- A1: Vascular margin
- A2: Uretal margin
- A3-6: Mass to inked margin
- A7: Mass toward pelvis
- A8: Mass to hilar fat
- A9: Mass to normal kidney parenchyma
- A10: Normal kidney parenchyma

Pathology Resident
Microscopic Description
Performed and incorporated in the report.

The staff pathologist listed below has reviewed this case.

****Electronically Signed Out****

Staff Pathologist

Diagnostic Discrepancy		✓
Primary Discrepancy		✓

Source: NCI Genomic Data Commons file f432f2c3-81f6-4153-9496-ac3bbb483155 (TCGA-MM-A563.0FD82DFD-7411-4BFB-961C-EC0A5B398EB9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).